FM case AD8576 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Penis.
https://portal.gdc.cancer.gov/cases/96bfcb60-91ed-446d-b26b-13effbc2e517

Male, 46.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the penis; primary biopsied or resected from the penis. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
